FM case AD156 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/b5d7d7d4-c007-46da-b957-db17ccd43d26

Male, 57.1 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the kidney. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
